Gene-level copy-number profile of tumor specimen ALCH-B3KQ-TTP1-A from ALCHEMIST case ALCH-B3KQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.2 years (21,272 days).
Specimen ALCH-B3KQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3c37f427-1588-447b-a0d4-4eebe559dfcf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3KQ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/de432c8d-a032-40c9-820c-0a019a110c70

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 85; copy number 1: 25,022; copy number 2: 26,324; copy number 3: 5,643; copy number 4: 1,004; copy number 5: 187; copy number 6: 25; copy number 7: 55; copy number 9: 18; copy number 10: 30; copy number 13: 1; copy number 15: 3; copy number 20: 1.

Homozygous deletions (total copy number 0; autosomes only): 85 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:91,684,447–91,685,884, 1 gene: DRD5P1.
- chr4:49,502,145–49,589,529, 11 genes: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr9:21,106,543–24,905,735, 68 genes (broad region; genes not listed).
- chr9:136,830,957–136,831,023, 1 gene (within-gene range 0–2): MIR4292.
- chr16:56,351,886–56,353,524, 1 gene (within-gene range 0–4): AC009102.2.
- chr17:36,591,879–36,634,698, 3 genes: DHRS11, MRM1, AC243830.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 320 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:200,027,614–200,177,420, 1 gene, copy number 5 (within-gene range 3–5): NR5A2.
- chr1:200,147,531–201,946,588, 48 genes, copy number 5: AC096633.1, CCNQP1, LINC00862, AC097065.2, AC097065.1, AC104461.1, ZNF281, AL359834.1, KIF14, DDX59, DDX59-AS1, CAMSAP2, RPL34P6, GPR25, INAVA, MROH3P, RNU6-704P, KIF21B, AL358473.1, AL358473.2, CACNA1S, ASCL5, TMEM9, IGFN1, AC103925.1, PKP1, TNNT2, AC119427.2, LAD1, TNNI1, AC096677.3, PHLDA3, AC096677.2, CSRP1, AC096677.1, RPS10P7, NAV1, AC092800.1, IPO9-AS1, MIR5191, AL645504.1, RNU6-501P, MIR1231, IPO9, MIR6739, SHISA4, AL513217.1, LMOD1.
- chr1:202,590,596–202,710,454, 1 gene, copy number 6 (within-gene range 4–6): SYT2.
- chr1:202,632,428–207,099,993, 151 genes, copy number 5–10 (within-gene range 3–10) (broad region; genes not listed).
- chr2:64,524,305–64,863,626, 11 genes, copy number 5: AFTPH, MIR4434, RNU6-100P, LINC02579, SERTAD2, AC007365.1, RPS10P9, RN7SL341P, Y_RNA, AC007880.1, LINC01800.
- chr2:64,906,863–64,907,138, 1 gene, copy number 5: RN7SL211P.
- chr2:66,235,377–66,731,223, 9 genes, copy number 5: AC118345.1, AC092669.1, MIR4778, LINC01873, MEIS1-AS3, MEIS1, MEIS1-AS2, LINC01798, LINC01797.
- chr7:74,773,962–74,789,376, 1 gene, copy number 13: NCF1.
- chr9:136,848,724–136,860,799, 2 genes, copy number 5 (within-gene range 2–5): PHPT1, MAMDC4.
- chr9:137,027,464–137,037,957, 2 genes, copy number 6 (within-gene range 1–6): C9orf139, FUT7.
- chr9:137,227,502–137,229,640, 1 gene, copy number 6: RNF224.
- chr16:9,753,404–11,182,186, 37 genes, copy number 5: GRIN2A, AC007218.2, AC007218.3, AC133565.1, IMPDH1P11, AC022168.1, RN7SL493P, ATF7IP2, AC131649.1, AC131649.2, RNU6-633P, LINC01290, EMP2, AC027277.1, AC027277.2, TEKT5, AC007595.1, MTCYBP33, MTND6P33, MTND5P33, MTND4P34, MTND4LP24, MTND3P13, MTCO3P24, MTATP6P24, NUBP1, TVP23A, AC133065.2, AC133065.1, CIITA, DEXI, AC133065.3, CLEC16A, RPL7P46, AC007014.2, AC007014.1, AC007220.2.
- chr16:48,165,773–48,850,015, 20 genes, copy number 6 (within-gene range 3–6): ABCC11, LONP2, UBA52P8, AC023818.1, SIAH1, Metazoa_SRP, AC026470.3, AC026470.1, MOCS1P1, N4BP1, AC026470.2, RPS2P44, AC023813.2, AC023813.1, AC007611.1, AC023813.3, AC023813.4, KLF8P1, RNU6-257P, AC023827.1.
- chr16:52,552,084–53,703,938, 31 genes, copy number 5: CASC16, AC026462.5, AC026462.3, AC026462.2, AC026462.4, AC026462.1, PHBP21, AC007346.1, AC007346.2, AC007906.2, CHD9, AC007906.1, AC079416.4, AC079416.2, AC079416.3, AC079416.1, RNA5SP427, AC007342.2, AC007342.3, AC007342.4, AC007342.5, AC007342.8, AC007342.9, RBL2, RNU6-1153P, AC007342.1, AC007342.6, AC007342.7, AKTIP, RPGRIP1L, AC007497.1.
- chr21:43,414,483–43,479,534, 4 genes, copy number 15–20: SIK1, LINC00319, LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 22,678. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
